Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3IM, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3IM-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age)

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

INPATIENT

Additional Copy to:

Clinical Diagnosis & History:

year old male with bladder diverticulum with high grade tumor.

Specimens Submitted:

- 1: Soft tissue bladder margin (fs)
- 2: Bladder diverticulum, urachus, perivesicle tissue, lymph nodes, upper portion of bladder, distal right ureter
- 3: Right vas deferens
- 4: Right pelvic lymph nodes
- 5: Perivesical fat
- 6: Piece of omentum
- 7: Periureteral tissue
- 8: Perivesical tissue

DIAGNOSIS:

1. Soft tissue, bladder margin; excision (fs):

- Benign fibroadipose tissue.

2. Bladder diverticulum, urachus, perivesicle tissue, lymph nodes, upper portion of bladder, distal right ureter:

Tumor Type:

Urothelial carcinoma with mixed histologic features, including: urothelial carcinoma NOS, keratinizing squamous and small cell/neuroendocrine involving a bladder diverticulum

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Papillary and flat

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Identified

Bladder Local Invasion:

Perivesical soft tissues

Extravesical Tumor Extension:

Right ureter uninvolved

Left ureter uninvolved

Urethra uninvolved

Vascular Invasion:

Identified

Perineural Invasion:

ICD-O-3

carcinoma, urothelial, keratinizing, NOS and
small cell, neuroendocrine
8071/3
8041/3

(Code to highest)

Site: bladder, NOS C67.9

hw
12/12/11

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

Exhibiting chronic cystitis

Exhibiting denudation

Prostate:

Not identified

Seminal Vesicles:

Not identified

Perivesical Lymph Nodes:

Not identified

The Pathologic Stage is (AJCC 2002):

pT3 (Invasion of perivesicle soft tissue)

3. Vas deferens, right; resection:

- Benign vas deferens.

4. Right pelvic lymph nodes:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 8

5. Soft tissue , perivesical fat; excision:

- Benign fibroadipose tissue.

6. Omentum; resection:

- Benign adipose tissue.

7. Soft tissue, periureteral tissue; excision:

- Benign fibrovascular and adipose tissue.

8. Soft tissue, perivesical tissue; excision:

- Benign fibroadipose tissue.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	SYN	
	CHR	
	AE1:AE3	
	TTF-1	

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

RECUT
IMM RECUT
NEG CONT

Gross Description:

1. The specimen is received fresh for frozen section consultation, labeled, "Soft tissue bladder margin (fs)" and consists of a fragment of soft pink and yellow tissue (1.5x 0.6x 0.3 cm). The specimen is entirely frozen and submitted in one cassette.

Summary of sections:
FSC - frozen section control

2). The specimen is received fresh labeled "Urachus, perivesicular tissue lymph nodes, upper portion of bladder, bladder diverticulum, distal right ureter" and consists of a portion of bladder, diverticulum, portion of ureter, and perivesicular tissue. The portion of bladder is received opened with a dusky purple-pink but otherwise unremarkable mucosa measuring 8.6 x 7.5 cm with underlying perivesicular tissue measuring 11.0 x 9.5 x 1.5 cm. The attached closed pouch like diverticulum measures 7.2 x 6.0 x 3.0 cm and is attached by a 1.8 x 0.5cm piece of the opened bladder mucosa. The anterior wall of the diverticulum displays a 1.8 x 1.5 cm transmural defect of a possible urachus, the tissue surrounding the defect is inked orange, the remaining anterior aspect is inked black. The posterior surface of both the diverticulum and bladder perivesicular tissue are inked blue. The right aspect of the diverticulum has an adhered segment of ureter measuring 3.0 cm in length by 0.5 cm in diameter. The ureter has one clip and an opposing opened end. The diverticulum is opened to reveal a yellow-brown fungating papillary friable tumor measuring 4.7 x 4.3 x 1.5 cm, 4.1 cm from the transmural defect and 1.0 cm from the attached bladder mucosa. There is a second adjacent raised papillary nodule measuring 2.5 x 2.2 x 0.9 cm, 0.2 cm from the fungating tumor, 2.0 cm from the transmural defects, and 5.6 cm from the attached bladder mucosa. Upon sectioning the two tumor nodules join and there is papillary extension to a depth of 1.8cm. The remaining bladder diverticulum mucosa is yellow and smooth. The tumor is 1.0 cm from the attached ureter and the ureter is grossly uninvolved with the tumor. Both of the ureter margins are shaved and submitted en face. Perpendicular sections of the bladder mucosa margins are submitted per clock face with 12 o'clock arbitrarily designated in pathology by the diverticulum attachment site. Gross photos are taken. is taken. Representative sections are submitted.

Summary of sections:
BM3 - bladder margin 3 o'clock
BM6- lateral margin 6 o'clock (opposite the diverticulum attachment site)
BM9 - bladder margin 9 o'clock
TB - diverticulum tumor to attached portion of bladder
TN - diverticulum tumor to smaller nodule
ND - smaller nodule to transmural defect
TU - tumor to ureter
UC - ureter margin (clipped end)
UO - ureter margin (opened end)
DIV - additional representative sections of diverticulum
BL - additional representative sections of bladder
F - tumor to greatest depth of invasion

3. The specimen is received in formalin, labeled "right vas deferens," and consists of a segment of vas deferens that measures 3.1x 0.6 x 0.4 cm. The specimen is serially sectioned and entirely submitted.

Summary of sections:
U - undesignated

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

4.The specimen is received in formalin, labeled "right pelvic lymph nodes," and consists of multiple lymph nodes that measure up to 2.2 cm in greatest dimension. The specimen is entirely submitted.

Summary of sections:

BLN - bisected lymph node

LN - lymph nodes

5.The specimen is received in formalin, labeled "perivesical fat," and consists of a piece of fibrofatty tissue that measures 5.8 x 4.2 x 1.5 cm. The specimen is serially sectioned to reveal yellow, homogeneous cut surfaces. Representative sections are submitted.

Summary of sections:

U -- undesignated

6.The specimen is received in formalin, labeled "piece of omentum," and consists of a piece of fibrofatty tissue that measures 7.9 x 3.2 x 2.8 cm. The specimen is serially sectioned to reveal yellow, homogenous cut surfaces. Representative sections are submitted.

Summary of sections:

U -- undesignated

7.The specimen is received in formalin, labeled "perivesical tissue" and consists of a piece of fibrofatty tissue that measures 2.3 x 1.8 X 0.4 cm. The specimen is entirely submitted.

Summary of sections:

U -- undesignated

8.The specimen is received in formalin, labeled "periureteral tissue" and consists of a piece of fibrofatty tissue that measures 0.5 x 0.4 x 0.4 cm. The specimen is entirely submitted.

Summary of sections:

U -- undesignated

Summary of Sections:

Part 1: Soft tissue bladder margin (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Bladder diverticulum, urachus, perivesicle tissue, lymph nodes, upper portion of bladder, distal right ureter

Block	Sect. Site	PCs
2	BL	2
1	BM3	1
1	BM6	1
1	BM9	1
2	DIV	2
2	F	2
1	ND	1
1	T	1
4	TB	4
3	TN	3
2	TU	2
1	UC	1
1	UO	1

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

Part 3: Right vas deferens

Block	Sect. Site	PCs
1	U	2

Part 4: Right pelvic lymph nodes

Block	Sect. Site	PCs
2	BLN	3
2	LN	3

Part 5: Perivesical fat

Block	Sect. Site	PCs
1	U	2

Part 6: Piece of omentum

Block	Sect. Site	PCs
1	U	2

Part 7: Periureteral tissue

Block	Sect. Site	PCs
1	U	2

Part 8: Perivesical tissue

Block	Sect. Site	PCs
1	U	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Soft tissue bladder margin (fs): Benign fibroadipose tissue (
Permanent diagnosis: SAME

Source: NCI Genomic Data Commons file 2da8a4ce-f798-4766-9cf6-11a754e853e2 (TCGA-DK-A3IM.860A2391-F5B1-4E5B-AEDB-FD318817F1F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).